Somatic mutation profile of tumor specimen ALCH-B1RN-TTP1-A (aliquot ALCH-B1RN-TTP1-A-3-0-D-A76I-36) from ALCHEMIST case ALCH-B1RN, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 55.1 years (20,130 days).
Specimen ALCH-B1RN-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b8346199-01ff-444e-bc1a-aeb0e4ecd922.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1RN-NB1-A (Blood Derived Normal), aliquot ALCH-B1RN-NB1-A-1-0-D-A76I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0b99d19c-2ff7-4772-b3ea-0f8010cb03a4

The open-access MAF lists 75 somatic variants for this specimen: 56 protein-altering or splice-affecting, 14 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 14, Nonsense Mutation 5, Intron 3, 3'Flank 1, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.824G>T p.C275F | Missense Mutation (SNP) | VAF 16/502 reads (3%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs863224451, CM076568, CM951234, COSV52661919, COSV52663595, COSV52675710, COSV52772708; ClinVar: likely pathogenic; called by muse, mutect2
- ATXN7L1 | c.1642A>G p.I548V | Missense Mutation (SNP) | VAF 13/270 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1252810517; called by muse, mutect2
- COBL | c.2942C>T p.S981F | Missense Mutation (SNP) | VAF 33/383 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV99035711; called by muse, mutect2
- DCAF12L2 | c.445G>T p.G149C | Missense Mutation (SNP) | VAF 7/125 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV63580123; called by muse, mutect2
- FBXL7 | c.1392C>G p.C464W | Missense Mutation (SNP) | VAF 10/186 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61644815; called by muse, mutect2
- FLT4 | c.875C>G p.S292C | Missense Mutation (SNP) | VAF 16/268 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.928); catalogued as COSV56098383; called by muse, mutect2
- FREM3 | c.4824C>A p.Y1608* | Nonsense Mutation (SNP) | VAF 47/288 reads (16%) | catalogued as rs1274484189; called by muse, mutect2, varscan2
- JAKMIP3 | c.490G>A p.A164T | Missense Mutation (SNP) | VAF 19/362 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.749); catalogued as rs778567934, COSV53827124; called by muse, mutect2
- MKRN3 | c.725G>T p.R242L | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.061); catalogued as COSV58810109; called by muse, mutect2
- MSH2 | c.2073T>G p.I691M | Missense Mutation (SNP) | VAF 43/906 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); catalogued as rs779101144; ClinVar: uncertain significance; called by muse, mutect2
- NADSYN1 | c.1489G>A p.A497T | Missense Mutation (SNP) | VAF 51/217 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV100034761; called by muse, varscan2
- OR2T12 | c.370G>C p.V124L | Missense Mutation (SNP) | VAF 15/376 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.285); catalogued as COSV58779524; called by muse, mutect2
- PCDHB16 | c.679C>G p.Q227E | Missense Mutation (SNP) | VAF 16/286 reads (6%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.005); catalogued as COSV99032813; called by muse, mutect2
- PIK3C2G | c.3434A>G p.N1145S (on ENST00000676171; = p.N1104S on NM_004570.5) | Missense Mutation (SNP) | VAF 20/300 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779252571; called by muse, mutect2
- SEZ6 | c.1241C>T p.A414V | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.033); catalogued as COSV57979504; called by mutect2, varscan2
- SHANK2 | c.2243G>A p.R748H | Missense Mutation (SNP) | VAF 12/298 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs932534804, COSV53591868; called by muse, mutect2
- SNTG1 | c.-25G>A | Splice Region (SNP) | VAF 11/255 reads (4%) | catalogued as rs1413708323; called by muse, mutect2
- THSD7A | c.3987G>T p.M1329I | Missense Mutation (SNP) | VAF 21/555 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV101439775; called by muse, mutect2
- TMCO1 | c.545G>A p.R182Q (on ENST00000612311 / NM_001256164.1; = p.R131Q on NM_019026.6) | Missense Mutation (SNP) | VAF 30/558 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.104); catalogued as COSV63317541; called by muse, mutect2
- ACSM2B | c.104G>A p.W35* | Nonsense Mutation (SNP) | VAF 12/454 reads (3%) | called by muse, mutect2
- APBA2 | c.820C>G p.P274A | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); called by muse, mutect2
- BEST2 | c.1375G>A p.E459K | Missense Mutation (SNP) | VAF 16/145 reads (11%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- BEST2 | c.1376A>T p.E459V | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- BRINP3 | c.617A>T p.K206M | Missense Mutation (SNP) | VAF 36/404 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2
- C1orf174 | c.526C>T p.P176S | Missense Mutation (SNP) | VAF 14/406 reads (3%) | SIFT tolerated (0.59); PolyPhen benign (0.268); called by muse, mutect2
- C9 | c.1013T>G p.F338C | Missense Mutation (SNP) | VAF 19/513 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- CCDC168 | c.18714A>T p.L6238F | Missense Mutation (SNP) | VAF 12/210 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.062); called by muse, mutect2
- CCR7 | c.470C>T p.A157V | Missense Mutation (SNP) | VAF 10/170 reads (6%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.823); called by muse, mutect2
- CENPE | c.5242A>C p.T1748P | Missense Mutation (SNP) | VAF 10/232 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.649); called by muse, mutect2
- CFAP47 | c.7136C>A p.P2379H | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CLTCL1 | c.1556G>T p.R519M | Missense Mutation (SNP) | VAF 14/508 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CRB1 | c.956G>T p.S319I | Missense Mutation (SNP) | VAF 32/524 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.25); called by muse, mutect2
- DNAH6 | c.2323G>C p.V775L | Missense Mutation (SNP) | VAF 20/704 reads (3%) | SIFT tolerated (0.32); PolyPhen benign (0.003); called by muse, mutect2
- ENPEP | c.2269G>T p.D757Y | Missense Mutation (SNP) | VAF 24/496 reads (5%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.651); called by muse, mutect2
- ERC1 | c.3031C>T p.Q1011* (on ENST00000360905 / NM_178040.4; = p.Q983* on NM_178039.4) | Nonsense Mutation (SNP) | VAF 6/133 reads (5%) | called by muse, mutect2
- GREB1L | c.1000C>T p.P334S | Missense Mutation (SNP) | VAF 26/529 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.187); called by muse, mutect2
- IGKV1D-17 | c.74A>G p.Q25R | Missense Mutation (SNP) | VAF 26/578 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.072); called by muse, mutect2
- IRF6 | c.980G>C p.C327S | Missense Mutation (SNP) | VAF 13/155 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.741); called by muse, mutect2
- LPAR4 | c.830C>T p.S277F | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- LRCH2 | c.539C>T p.P180L | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MBOAT1 | c.805G>A p.D269N | Missense Mutation (SNP) | VAF 16/552 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); called by muse, mutect2
- MYO1A | c.130G>A p.V44M | Missense Mutation (SNP) | VAF 13/325 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NLRP5 | c.341A>G p.H114R | Missense Mutation (SNP) | VAF 11/284 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.069); called by muse, mutect2
- NOP14 | c.1492T>G p.L498V | Missense Mutation (SNP) | VAF 15/320 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2
- PCDH15 | c.5762C>T p.S1921L | Missense Mutation (SNP) | VAF 7/169 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.04); called by muse, mutect2
- PLXNB1 | c.3893A>T p.Q1298L | Missense Mutation (SNP) | VAF 11/220 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.109); called by muse, mutect2
- PRL | c.20C>A p.P7Q | Missense Mutation (SNP) | VAF 18/544 reads (3%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.055); called by muse, mutect2
- RPS26 | c.227G>T p.S76I | Missense Mutation (SNP) | VAF 23/601 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- SYN2 | c.88G>T p.E30* | Nonsense Mutation (SNP) | VAF 5/51 reads (10%) | called by muse, mutect2
- TAF1L | c.1933G>T p.G645C | Missense Mutation (SNP) | VAF 24/498 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- TAFA5 | c.351G>A p.W117* (on ENST00000402357 / NM_001082967.3; = p.W110* on NM_015381.7) | Nonsense Mutation (SNP) | VAF 6/72 reads (8%) | called by muse, mutect2
- TBC1D8 | c.993C>A p.S331R | Missense Mutation (SNP) | VAF 10/188 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TBX15 | c.454G>T p.G152C (on ENST00000369429 / NM_001330677.2; = p.G46C on NM_152380.3) | Missense Mutation (SNP) | VAF 23/710 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.729); called by muse, mutect2
- TRIM58 | c.1426G>A p.D476N | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.018); called by mutect2, varscan2
- UMOD | c.1505T>C p.L502P | Missense Mutation (SNP) | VAF 18/430 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- ZNF780B | c.1250A>T p.Y417F | Missense Mutation (SNP) | VAF 47/424 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- AMHR2 | c.147C>T p.L49= | Silent (SNP) | VAF 20/311 reads (6%) | called by muse, mutect2
- ANO4 | c.2196A>T p.L732= (on ENST00000392977 / NM_001286615.2; = p.L697= on NM_178826.4) | Silent (SNP) | VAF 14/288 reads (5%) | called by muse, mutect2
- ATP10B | c.2443C>T p.L815= | Silent (SNP) | VAF 19/534 reads (4%) | called by muse, mutect2
- ATP13A5 | c.2796T>C p.N932= | Silent (SNP) | VAF 8/173 reads (5%) | called by muse, mutect2
- FMN2 | c.2244C>A p.P748= | Silent (SNP) | VAF 21/297 reads (7%) | catalogued as rs750936446, COSV100143840; called by muse, mutect2
- OR52E4 | c.706C>T p.L236= | Silent (SNP) | VAF 18/416 reads (4%) | called by muse, mutect2
- OR6P1 | c.609C>A p.A203= | Silent (SNP) | VAF 44/490 reads (9%) | catalogued as COSV58108911; called by muse, mutect2
- SECISBP2 | c.420A>G p.K140= | Silent (SNP) | VAF 20/678 reads (3%) | called by muse, mutect2
- SETD1A | c.948A>G p.A316= | Silent (SNP) | VAF 14/273 reads (5%) | called by muse, mutect2
- SYNE1 | c.16665A>G p.A5555= (on ENST00000367255 / NM_182961.4; = p.A5484= on NM_033071.3) | Silent (SNP) | VAF 26/604 reads (4%) | catalogued as rs1042078718, COSV55047361; called by muse, mutect2
- TDRD6 | c.2562T>C p.Y854= | Silent (SNP) | VAF 12/172 reads (7%) | catalogued as rs1255016496; called by muse, mutect2
- TEX13C | c.309C>A p.T103= | Silent (SNP) | VAF 18/197 reads (9%) | called by muse, mutect2
- TMIGD2 | c.594G>T p.R198= | Silent (SNP) | VAF 11/243 reads (5%) | called by muse, mutect2
- TRMT61B | c.1233T>G p.S411= | Silent (SNP) | VAF 14/191 reads (7%) | called by muse, mutect2
- CICP28 | chr7:56811973 C>A | 3'Flank (SNP) | VAF 22/194 reads (11%) | catalogued as rs1159317847; called by muse, mutect2, varscan2
- GALNT14 | c.129+23145G>C | Intron (SNP) | VAF 13/348 reads (4%) | called by muse, mutect2
- MUC19 | n.5374C>A | RNA (SNP) | VAF 16/502 reads (3%) | catalogued as rs1295064268; called by muse, mutect2
- RBM4 | c.412+47A>T | Intron (SNP) | VAF 11/131 reads (8%) | called by muse, mutect2
- RPS27A | c.103+36G>T | Intron (SNP) | VAF 20/402 reads (5%) | catalogued as rs1327612055; called by muse, mutect2
